Somatic mutation profile of tumor specimen HCM-WCMC-0952-C34-01A (aliquot HCM-WCMC-0952-C34-01A-45D-A88H-36) from HCMI case HCM-WCMC-0952-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Large cell neuroendocrine carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 74.0 years (27,036 days).
Specimen HCM-WCMC-0952-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d383eac-8b9f-4906-8187-bc785acdeae2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0952-C34-10A (Blood Derived Normal), aliquot HCM-WCMC-0952-C34-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c532cbd-5869-4974-ae17-a591f2657663

The open-access MAF lists 999 somatic variants for this specimen: 743 protein-altering or splice-affecting, 217 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 659, Silent 217, Nonsense Mutation 38, Intron 22, Frame Shift Del 12, Splice Site 10, Splice Region 9, Frame Shift Ins 8, 5'UTR 5, 5'Flank 4, RNA 3, 3'Flank 3.

Variants (750 of 999; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RYR2 | c.1250G>T p.R417L | Missense Mutation (SNP) | VAF 120/431 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs751428303, COSV63688268, COSV63692084; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 97/172 reads (56%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACHE | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 41/330 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53815131; called by muse, mutect2, varscan2
- ACOX2 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1469171650; called by muse, mutect2, varscan2
- ACSM4 | c.916del p.L306* | Frame Shift Del (DEL) | VAF 106/376 reads (28%) | catalogued as COSV68069152; called by mutect2, varscan2
- ADAM19 | c.468G>C p.K156N | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV99067877; called by muse, mutect2, varscan2
- ADCY9 | c.3144G>T p.Q1048H | Missense Mutation (SNP) | VAF 19/343 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1167697653, COSV53570692; called by muse, mutect2
- ADGRB3 | c.2481G>T p.T827= | Splice Region (SNP) | VAF 30/258 reads (12%) | catalogued as COSV99483594; called by muse, mutect2, varscan2
- ALK | c.4019A>T p.E1340V | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66563832; called by muse, varscan2
- ANAPC10 | c.380A>G p.N127S | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1356393194; called by muse, mutect2, varscan2
- ANK1 | c.3416G>T p.R1139L | Missense Mutation (SNP) | VAF 94/289 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV55891781; called by muse, mutect2, varscan2
- ANKLE2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.011); catalogued as rs1174045591; called by muse, mutect2, varscan2
- APOA4 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs763972330, COSV63360127; called by muse, mutect2
- ARID2 | c.3868G>T p.V1290L | Missense Mutation (SNP) | VAF 213/771 reads (28%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs777982636; called by muse, mutect2, varscan2
- ASB5 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 224/407 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV56668728; called by mutect2, varscan2
- ATP10A | c.2426G>T p.R809L | Missense Mutation (SNP) | VAF 93/252 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776829827, COSV63516508, COSV63516647, COSV63518546; called by muse, mutect2, varscan2
- ATP11C | c.3396G>C p.L1132F | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59569153; called by muse, mutect2, varscan2
- ATP2A3 | c.3006G>T p.R1002S | Missense Mutation (SNP) | VAF 123/206 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV59232323; called by muse, mutect2, varscan2
- ATP4A | c.2651T>C p.M884T | Missense Mutation (SNP) | VAF 151/383 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs769514644; called by muse, mutect2, varscan2
- AVIL | c.1631T>C p.L544P | Missense Mutation (SNP) | VAF 45/704 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1185387963; called by muse, mutect2
- BMP1 | c.904A>T p.R302W | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100110064; called by muse, mutect2, varscan2
- BSCL2 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99628019; called by muse, mutect2, varscan2
- BTNL8 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.461); catalogued as COSV51460359; called by muse, mutect2, varscan2
- C12orf56 | c.1543A>G p.I515V (on ENST00000543942 / NM_001170633.2; = p.I355V on NM_001099676.3) | Missense Mutation (SNP) | VAF 189/533 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs576278397; called by muse, mutect2, varscan2
- CACNA1E | c.2203G>T p.V735F | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as rs528168265, COSV62395483; called by muse, mutect2, varscan2
- CCDC168 | c.18475C>A p.P6159T | Missense Mutation (SNP) | VAF 128/279 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV59425103; called by muse, mutect2, varscan2
- CD48 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 106/321 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs756875746; called by muse, mutect2, varscan2
- CDH20 | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs868864755; called by muse, mutect2, varscan2
- CDH24 | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 54/183 reads (30%) | catalogued as rs1301312949; called by muse, mutect2, varscan2
- CDK14 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs768515404; called by muse, mutect2, varscan2
- CENPF | c.8657C>T p.A2886V | Missense Mutation (SNP) | VAF 56/716 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV65275833; called by muse, mutect2
- CEP128 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV53679068, COSV53679196; called by muse, mutect2, varscan2
- CES1 | c.1189C>G p.P397A (on ENST00000361503 / NM_001025194.2; = p.P396A on NM_001266.5) | Missense Mutation (SNP) | VAF 25/409 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs758236680, COSV62086610; called by muse, mutect2
- CFAP61 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 122/493 reads (25%) | catalogued as rs200778448; called by muse, mutect2, varscan2
- CLASP1 | c.3713G>T p.R1238L | Missense Mutation (SNP) | VAF 44/238 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV55312830, COSV99752631; called by muse, mutect2, varscan2
- CLDN1 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 95/956 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as rs373107390; ClinVar: uncertain significance; called by muse, mutect2
- CLDN23 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 43/314 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as rs756963928, COSV101093015; called by muse, mutect2, varscan2
- CLN8 | c.248G>T p.W83L | Missense Mutation (SNP) | VAF 222/442 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs780923228; called by muse, varscan2
- CNN3 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as COSV64637260; called by muse, mutect2, varscan2
- CNTNAP5 | c.2954C>T p.T985I | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV70489147; called by muse, mutect2, varscan2
- COL3A1 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 246/545 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58597871; called by muse, mutect2, varscan2
- COL4A2 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 90/175 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476249623, COSV64630856; called by muse, mutect2, varscan2
- CR1L | c.301G>T p.D101Y | Missense Mutation (SNP) | VAF 33/502 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54331054; called by muse, mutect2
- CSMD1 | c.9575C>G p.S3192C (on ENST00000520002; = p.S3191C on NM_033225.6) | Missense Mutation (SNP) | VAF 220/454 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59304948; called by muse, mutect2, varscan2
- CST2 | c.116T>A p.L39H | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as COSV59030211; called by muse, mutect2, varscan2
- CTDSPL | c.598C>G p.H200D (on ENST00000273179 / NM_001008392.2; = p.H189D on NM_005808.3) | Missense Mutation (SNP) | VAF 253/430 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV56205880; called by muse, mutect2, varscan2
- DAOA | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 160/375 reads (43%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs757009026, COSV100298829, COSV61601843; called by muse, mutect2, varscan2
- DLGAP1 | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 94/401 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV59839385; called by muse, mutect2, varscan2
- DNAH14 | c.5771G>T p.R1924L (on ENST00000445597; = p.R2464L on NM_001367479.1) | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs932845004; called by muse, mutect2, varscan2
- DNASE1L2 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 35/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1341584024; called by mutect2, varscan2
- DOCK10 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV51421253; called by muse, mutect2, varscan2
- DPP10 | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV59684506; called by muse, mutect2, varscan2
- DSC3 | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 83/324 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs147196455; called by muse, mutect2, varscan2
- DVL3 | c.1028G>C p.G343A | Missense Mutation (SNP) | VAF 170/401 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV100493609; called by muse, mutect2, varscan2
- EPHA8 | c.1173C>A p.S391R | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs767106998; called by muse, mutect2, varscan2
- EPHB6 | c.2164G>T p.A722S | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.223); catalogued as rs370383805; called by muse, mutect2, varscan2
- ERCC3 | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs753633161; called by muse, mutect2, varscan2
- EYA2 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 132/408 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs774269626; called by muse, mutect2, varscan2
- FAM47C | c.1085G>T p.R362L | Missense Mutation (SNP) | VAF 135/289 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.397); catalogued as rs149671724, COSV63725620; called by mutect2, varscan2
- FLG | c.2663G>A p.G888E | Missense Mutation (SNP) | VAF 145/530 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.428); catalogued as COSV64245104; called by muse, mutect2, varscan2
- FSIP2 | c.12223A>G p.I4075V | Missense Mutation (SNP) | VAF 129/584 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1260661207; called by muse, mutect2, varscan2
- FYCO1 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 141/458 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs769815234; called by muse, mutect2, varscan2
- GABRA2 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 150/580 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); catalogued as COSV100734542; called by muse, varscan2
- GDPD4 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV60019412; called by muse, mutect2, varscan2
- GIPC3 | c.652G>T p.G218W | Missense Mutation (SNP) | VAF 165/272 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59260993; called by muse, mutect2, varscan2
- GLP1R | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs148543734; called by muse, mutect2, varscan2
- GLP2R | c.1362C>G p.F454L | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV52323474; called by muse, mutect2, varscan2
- GOLGA6L2 | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756271412; called by muse, mutect2, varscan2
- GPD1 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 55/574 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201609436; called by muse, mutect2
- GPR20 | c.584G>A p.C195Y | Missense Mutation (SNP) | VAF 105/679 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs967035833; called by muse, mutect2, varscan2
- GRIN2A | c.2178C>A p.D726E | Missense Mutation (SNP) | VAF 32/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58018522; called by muse, mutect2, varscan2
- GRM8 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 75/359 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.764); catalogued as rs1021001584, COSV58815708; called by muse, mutect2, varscan2
- HOXD13 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as CM127648; called by muse, mutect2, varscan2
- HS3ST6 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 134/274 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as COSV99562619, COSV99562884; called by muse, mutect2, varscan2
- HSD17B14 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV54363080; called by muse, mutect2, varscan2
- HTT | c.7441G>T p.V2481L | Missense Mutation (SNP) | VAF 215/495 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV61866672; called by muse, mutect2, varscan2
- IGHV3-48 | c.197G>T p.W66L | Missense Mutation (SNP) | VAF 55/335 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.375); catalogued as rs1288243938; called by muse, mutect2, varscan2
- IGKV6D-21 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs776486396; called by muse, mutect2, varscan2
- IGLL5 | c.408T>A p.C136* | Nonsense Mutation (SNP) | VAF 110/303 reads (36%) | catalogued as rs565895977; called by muse, mutect2, varscan2
- ILDR2 | c.1559C>T p.T520I | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs1173751907; called by muse, mutect2, varscan2
- INCENP | c.1564C>G p.R522G | Missense Mutation (SNP) | VAF 63/333 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99611645; called by muse, mutect2, varscan2
- ITGA4 | c.232G>T p.A78S | Missense Mutation (SNP) | VAF 36/426 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs539227893; called by muse, mutect2
- ITPRID2 | c.2536C>T p.L846F | Missense Mutation (SNP) | VAF 114/480 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546606916; called by muse, mutect2, varscan2
- KCNA1 | c.144C>G p.F48L | Missense Mutation (SNP) | VAF 152/417 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV66836780; called by muse, varscan2
- KCNK2 | c.1069C>T p.R357W (on ENST00000444842 / NM_001017425.3; = p.R342W on NM_014217.4) | Missense Mutation (SNP) | VAF 147/515 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157701926, COSV67206955; called by muse, mutect2, varscan2
- KCNQ4 | c.214C>A p.R72S | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs778559114, COSV100714352; called by muse, mutect2, varscan2
- KCNQ5 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 214/467 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100571331; called by muse, mutect2, varscan2
- KIAA0586 | c.4100C>A p.S1367Y (on ENST00000619416 / NM_001244190.2; = p.S1306Y on NM_014749.5) | Missense Mutation (SNP) | VAF 58/249 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as rs758384631; called by muse, mutect2, varscan2
- KIAA1755 | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 52/385 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54079908; called by muse, mutect2, varscan2
- KMT2C | c.6290C>T p.P2097L | Missense Mutation (SNP) | VAF 43/400 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs746222774; called by muse, mutect2, varscan2
- KPTN | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 49/263 reads (19%) | catalogued as COSV52637876; called by muse, mutect2, varscan2
- KRTAP25-1 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 192/373 reads (51%) | SIFT tolerated (0.86); PolyPhen benign (0.048); catalogued as rs942081236; called by muse, mutect2, varscan2
- LAMB1 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as rs774790976; called by muse, mutect2, varscan2
- LARGE1 | c.2037G>T p.W679C | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61665402; called by muse, mutect2, varscan2
- LCE1E | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 96/328 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV64219734, COSV64220090; called by mutect2, varscan2
- LCE3C | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 60/265 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.796); catalogued as rs761242447; called by muse, mutect2, varscan2
- LLCFC1 | c.165G>T p.K55N (on ENST00000458732; = p.K24N on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/403 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as COSV62338470; called by muse, mutect2, varscan2
- LRFN5 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 122/391 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53273998, COSV99985271; called by muse, mutect2, varscan2
- LRFN5 | c.1583C>A p.T528N | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184494599; called by mutect2, varscan2
- LRP1B | c.7060G>T p.A2354S | Missense Mutation (SNP) | VAF 98/361 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as rs764571078; called by mutect2, varscan2
- LRP2 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.299); catalogued as COSV55539234; called by muse, mutect2, varscan2
- MAGI1 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 124/403 reads (31%) | catalogued as rs1380025378; called by muse, mutect2, varscan2
- MANEAL | c.788G>T p.S263I (on ENST00000373045 / NM_001113482.1; = p.S41I on NM_152496.2) | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs764965467; called by muse, mutect2, varscan2
- MAP3K10 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 45/295 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.104); catalogued as rs1410291514; called by muse, mutect2, varscan2
- MAST4 | c.3178A>G p.S1060G (on ENST00000403625 / NM_001164664.2; = p.S871G on NM_015183.3) | Missense Mutation (SNP) | VAF 57/512 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1390610366; called by muse, mutect2, varscan2
- MCF2 | c.142G>A p.A48T (on ENST00000520602; = p.A5T on NM_001099855.1) | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1463596448; called by muse, mutect2, varscan2
- MDGA1 | c.2409C>A p.Y803* | Nonsense Mutation (SNP) | VAF 38/274 reads (14%) | catalogued as COSV99776627; called by muse, mutect2, varscan2
- MFSD4A | c.355A>G p.M119V | Missense Mutation (SNP) | VAF 120/565 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754380474; called by muse, mutect2, varscan2
- MICB | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 33/393 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.341); catalogued as rs769806725; called by muse, mutect2
- MMP16 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 60/962 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1233813645, COSV54182591; called by muse, mutect2
- MRGPRX4 | c.391C>A p.R131S | Missense Mutation (SNP) | VAF 211/383 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1170513963, COSV100049611, COSV58589672; called by muse, mutect2, varscan2
- MTARC2 | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.173); catalogued as rs749638702; called by muse, mutect2, varscan2
- MYH1 | c.2622G>T p.R874S | Missense Mutation (SNP) | VAF 60/571 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV56852178; called by muse, mutect2, varscan2
- MYO5A | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs753155018, COSV100697655; called by muse, mutect2
- MYT1L | c.3089C>G p.P1030R | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67704798; called by muse, mutect2, varscan2
- NAV3 | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 129/440 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); catalogued as rs370224002, COSV57060374, COSV57084019; called by muse, mutect2, varscan2
- NHLRC2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 36/470 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV65175276; called by muse, mutect2
- NLGN4X | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 50/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320532; called by muse, mutect2, varscan2
- NPHS1 | c.2633dup p.N878Kfs*65 | Frame Shift Ins (INS) | VAF 29/227 reads (13%) | catalogued as rs1315968443; called by mutect2, varscan2
- NPRL3 | c.494G>A p.R165Q (on ENST00000611875 / NM_001077350.3; = p.R140Q on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/417 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs770570210; called by muse, mutect2, varscan2
- NRAP | c.792C>G p.Y264* | Nonsense Mutation (SNP) | VAF 230/337 reads (68%) | catalogued as rs940017622; called by muse, mutect2, varscan2
- NRXN1 | c.4213G>T p.V1405F | Missense Mutation (SNP) | VAF 73/322 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV60511107; called by muse, mutect2, varscan2
- OPCML | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 62/467 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs772142837; called by muse, mutect2, varscan2
- OPRK1 | c.813G>T p.R271S | Missense Mutation (SNP) | VAF 162/474 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55571827; called by muse, mutect2, varscan2
- OR13C2 | c.859A>T p.M287L | Missense Mutation (SNP) | VAF 136/276 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs142576527; called by muse, mutect2, varscan2
- OR14A16 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 154/548 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62926054, COSV62926187; called by muse, mutect2, varscan2
- OR2L5 | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 108/329 reads (33%) | catalogued as rs776623297; called by muse, mutect2, varscan2
- OR4A16 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 187/384 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as COSV100125459; called by muse, mutect2, varscan2
- OR4C6 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 97/448 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV58603783; called by muse, mutect2, varscan2
- OR5L2 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 211/477 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs267602980, COSV65723579; called by muse, mutect2, varscan2
- OR9I1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 104/304 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs769620522, COSV56926317; called by muse, mutect2, varscan2
- PCDH11X | c.2386C>A p.P796T | Missense Mutation (SNP) | VAF 229/497 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV53460250; called by muse, mutect2, varscan2
- PCDH7 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 224/530 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV100687640; called by muse, mutect2, varscan2
- PCDHA3 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 48/394 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1230044523, COSV63542712; called by muse, varscan2
- PCDHB5 | c.2164G>T p.G722C | Missense Mutation (SNP) | VAF 160/360 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.942); catalogued as COSV50659658; called by muse, mutect2, varscan2
- PEX1 | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 70/327 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV104373608; called by mutect2, varscan2
- PGR | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 50/431 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV54801187; called by muse, mutect2, varscan2
- PKD1 | c.2100C>A p.V700= | Splice Region (SNP) | VAF 16/343 reads (5%) | catalogued as CX150982; called by muse, mutect2
- PLA2R1 | c.172G>T p.V58F | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV51776357, COSV99323534; called by muse, mutect2, varscan2
- PLEKHD1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 68/213 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs760179013; called by muse, mutect2, varscan2
- PLPPR4 | c.2212C>A p.P738T | Missense Mutation (SNP) | VAF 188/383 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs768952470, COSV64567699; called by muse, mutect2, varscan2
- PLXND1 | c.3160C>T p.R1054W | Missense Mutation (SNP) | VAF 166/441 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs761956464, COSV100138842; called by muse, varscan2
- PMEPA1 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55692105; called by muse, mutect2, varscan2
- PNPLA5 | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV53374930; called by muse, mutect2, varscan2
- POLR2G | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as COSV57135589; called by muse, mutect2, varscan2
- POTEF | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV62541349; called by muse, mutect2, varscan2
- PPP3CA | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 152/283 reads (54%) | catalogued as COSV100548062; called by muse, mutect2, varscan2
- PRR32 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 68/471 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.054); catalogued as COSV64420353; called by muse, mutect2, varscan2
- PRRX2 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 121/195 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65242046; called by muse, mutect2, varscan2
- PTPRD | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 345/541 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61928224, COSV61933453; called by muse, mutect2, varscan2
- PTPRQ | c.1974G>C p.Q658H (on ENST00000616559; = p.Q616H on NM_001145026.2) | Missense Mutation (SNP) | VAF 161/496 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as COSV99030928; called by muse, mutect2, varscan2
- RABGGTA | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 93/331 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs201173826; called by muse, mutect2, varscan2
- RAD51AP2 | c.3383G>A p.R1128K | Missense Mutation (SNP) | VAF 139/394 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1314449454; called by muse, mutect2, varscan2
- RBMS2 | c.611C>G p.P204R | Missense Mutation (SNP) | VAF 16/409 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs1445818077, COSV56263802; called by muse, mutect2
- REL | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 90/296 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs373752427; called by muse, mutect2, varscan2
- RENBP | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 177/352 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs782603882; called by muse, mutect2, varscan2
- RESP18 | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1325080974; called by muse, mutect2, varscan2
- RHOF | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 206/467 reads (44%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); catalogued as rs779872355, COSV57363257; called by muse, mutect2, varscan2
- RIMBP2 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.843); catalogued as rs371818815, COSV55476584; called by muse, mutect2
- RNF17 | c.3091G>A p.V1031I | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs748172486; called by muse, mutect2, varscan2
- RNF181 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1342704126; called by muse, mutect2, varscan2
- RP1L1 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 72/323 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.171); catalogued as rs377751683; called by muse, mutect2, varscan2
- RPGRIP1 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV52855920; called by muse, mutect2, varscan2
- RPS6KA2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 74/391 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs749147718, COSV55826267, COSV99692157; called by muse, varscan2
- RPS6KC1 | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 114/566 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV65299372, COSV99055910; called by muse, mutect2, varscan2
- RYR2 | c.2018G>T p.W673L | Missense Mutation (SNP) | VAF 100/389 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757774138; called by muse, mutect2, varscan2
- RYR2 | c.7210C>A p.P2404T | Missense Mutation (SNP) | VAF 73/387 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1318711262, CM097959, COSV100768063; called by muse, mutect2, varscan2
- SCN9A | c.5500G>A p.D1834N (on ENST00000303354; = p.D1823N on NM_002977.3) | Missense Mutation (SNP) | VAF 111/423 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV57608701; called by muse, mutect2, varscan2
- SCYL1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs536228379; called by muse, mutect2, varscan2
- SELP | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs772189255, COSV55250004; called by muse, mutect2, varscan2
- SHISA6 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); catalogued as rs1256896744; called by muse, mutect2, varscan2
- SIGLEC11 | c.329del p.G110Afs*8 | Frame Shift Del (DEL) | VAF 17/126 reads (13%) | catalogued as COSV101389594; called by mutect2, varscan2
- SLC4A5 | c.1327G>A p.G443S | Missense Mutation (SNP) | VAF 65/475 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs776201138; called by muse, mutect2, varscan2
- SLIT3 | c.4412C>T p.S1471F | Missense Mutation (SNP) | VAF 39/389 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs956212203; called by muse, mutect2
- SMARCAL1 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 98/199 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771595818; called by muse, mutect2, varscan2
- SMARCB1 | c.562G>T p.V188L (on ENST00000263121; = p.V234L on NM_003073.5) | Missense Mutation (SNP) | VAF 120/410 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as rs1272912695; called by muse, mutect2, varscan2
- ST8SIA5 | c.606G>T p.M202I | Missense Mutation (SNP) | VAF 114/378 reads (30%) | PolyPhen benign (0.03); catalogued as COSV100164536, COSV59335365; called by muse, mutect2, varscan2
- STK36 | c.3773G>C p.R1258P | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99831756; called by muse, mutect2, varscan2
- STMN2 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 119/628 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV55221171, COSV99627078; called by muse, mutect2, varscan2
- SYT14 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 77/902 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs751630321, COSV99655414; called by muse, mutect2
- TAFA5 | c.316G>A p.E106K (on ENST00000402357 / NM_001082967.3; = p.E99K on NM_015381.7) | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60992616; called by muse, mutect2, varscan2
- TBC1D9 | c.2929G>T p.G977C | Missense Mutation (SNP) | VAF 107/484 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV101464346; called by mutect2, varscan2
- TBKBP1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 87/315 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64654129; called by muse, mutect2, varscan2
- TGIF2LX | c.496C>A p.Q166K | Missense Mutation (SNP) | VAF 156/314 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99383308; called by muse, mutect2, varscan2
- TLL1 | c.2110C>T p.Q704* | Nonsense Mutation (SNP) | VAF 253/458 reads (55%) | catalogued as COSV99288686; called by muse, mutect2, varscan2
- TMEM71 | c.438C>A p.N146K (on ENST00000523829 / NM_001382398.1; = p.N127K on NM_144649.3) | Missense Mutation (SNP) | VAF 142/747 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100785575, COSV63457207; called by muse, mutect2, varscan2
- TRIM22 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 164/320 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs372042006, COSV66090849; called by muse, mutect2, varscan2
- TRIM9 | c.272C>A p.P91Q | Missense Mutation (SNP) | VAF 107/340 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV53621044; called by muse, mutect2, varscan2
- TRPV3 | c.2173G>A p.E725K | Missense Mutation (SNP) | VAF 131/225 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375812083; called by muse, mutect2, varscan2
- TTN | c.94099C>A p.L31367I (on ENST00000591111; = p.L23943I on NM_003319.4) | Missense Mutation (SNP) | VAF 40/408 reads (10%) | PolyPhen benign (0.011); catalogued as COSV59968190; called by muse, mutect2
- TTN | c.76283C>A p.P25428Q (on ENST00000591111; = p.P18004Q on NM_003319.4) | Missense Mutation (SNP) | VAF 115/496 reads (23%) | PolyPhen possibly damaging (0.758); catalogued as COSV59907409, COSV60082814; called by muse, mutect2, varscan2
- TTN | c.67220G>T p.R22407I (on ENST00000591111; = p.R14983I on NM_003319.4) | Missense Mutation (SNP) | VAF 88/556 reads (16%) | PolyPhen benign (0.186); catalogued as COSV59863511; called by muse, mutect2, varscan2
- TUT4 | c.1634G>T p.W545L | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV57115833; called by muse, varscan2
- TXNRD1 | c.419A>G p.Y140C (on ENST00000525566 / NM_001093771.3; = p.Y42C on NM_003330.4) | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as rs1306122055; called by muse, mutect2
- UBA52 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 111/207 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV70615424; called by muse, mutect2, varscan2
- UNC13C | c.5653G>T p.A1885S | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.985); catalogued as COSV52845480; called by muse, mutect2, varscan2
- UNC80 | c.1897G>T p.E633* | Nonsense Mutation (SNP) | VAF 64/619 reads (10%) | catalogued as COSV99778591; called by muse, mutect2, varscan2
- USH2A | c.2553G>T p.K851N | Missense Mutation (SNP) | VAF 110/552 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.139); catalogued as rs781117624; called by muse, varscan2
- VCAN | c.3257G>C p.R1086T | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.236); catalogued as COSV54113044; called by muse, mutect2, varscan2
- VCAN | c.4337G>T p.S1446I | Missense Mutation (SNP) | VAF 170/366 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); catalogued as rs764331111; called by muse, varscan2
- VCAN | c.7572C>A p.F2524L | Missense Mutation (SNP) | VAF 107/249 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54096118; called by muse, mutect2, varscan2
- VCAN | c.7573A>G p.R2525G | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV54111358; called by muse, mutect2, varscan2
- VIPAS39 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs939430612; called by muse, mutect2, varscan2
- VIPR1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 124/359 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as rs766398547; called by muse, mutect2, varscan2
- XIRP2 | c.5985G>T p.M1995I (on ENST00000628543; = p.M2170I on NM_152381.6) | Missense Mutation (SNP) | VAF 60/632 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54737398; called by muse, mutect2
- XIRP2 | c.8740G>A p.E2914K (on ENST00000628543; = p.E3089K on NM_152381.6) | Missense Mutation (SNP) | VAF 202/457 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as rs1251526612; called by muse, mutect2, varscan2
- XRN1 | c.4691G>T p.G1564V | Missense Mutation (SNP) | VAF 152/482 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as rs960789057; called by muse, mutect2, varscan2
- ZBTB42 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs919456705, COSV61137132; called by muse, mutect2, varscan2
- ZDHHC17 | c.1668A>G p.I556M | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1187458926; called by muse, mutect2, varscan2
- ZFHX3 | c.60G>T p.Q20H | Missense Mutation (SNP) | VAF 30/297 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV51721237; called by muse, mutect2, varscan2
- ZFHX4 | c.1793C>G p.P598R | Missense Mutation (SNP) | VAF 257/694 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.79); catalogued as COSV99264243; called by muse, mutect2, varscan2
- ZHX2 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 70/837 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as rs759251479, COSV58714307; called by muse, mutect2
- ZNF142 | c.1234C>T p.R412W (on ENST00000411696 / NM_001379660.1; = p.R212W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 102/405 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1275178693; called by muse, mutect2, varscan2
- ZNF248 | c.907G>T p.G303W | Missense Mutation (SNP) | VAF 151/312 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs75080219; called by muse, mutect2, varscan2
- ZNF385D | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 222/383 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs1254145219; called by muse, mutect2, varscan2
- ZNF534 | c.1394C>T p.S465F (on ENST00000332323 / NM_001143939.3; = p.S452F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/444 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.046); catalogued as rs1408645488, COSV56517257; called by muse, mutect2, varscan2
- ZNF600 | c.1484A>G p.E495G | Missense Mutation (SNP) | VAF 222/532 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs1385771192; called by muse, mutect2, varscan2
- ZNF7 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs575469319; called by muse, mutect2
- ZNF804A | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56467272; called by muse, mutect2
- ZNF804B | c.1907A>T p.K636M | Missense Mutation (SNP) | VAF 157/376 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60823083; called by muse, mutect2, varscan2
- AADAC | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 69/704 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2
- ABCA13 | c.14570A>T p.Y4857F | Missense Mutation (SNP) | VAF 116/390 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCF3 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.435); called by muse, mutect2
- ABHD12 | c.1121A>G p.Y374C | Missense Mutation (SNP) | VAF 100/453 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ABHD16A | c.1547G>A p.G516E | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABTB2 | c.574G>C p.G192R | Missense Mutation (SNP) | VAF 189/295 reads (64%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC099489.1 | c.6380G>T p.W2127L | Missense Mutation (SNP) | VAF 44/333 reads (13%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2
- ACSM2B | c.125C>A p.A42D | Missense Mutation (SNP) | VAF 169/388 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ACTL9 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 153/265 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM18 | c.1925G>T p.C642F | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADAM20 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADAM23 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 43/507 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAMTS6 | c.2650G>T p.D884Y | Missense Mutation (SNP) | VAF 61/404 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADAMTSL1 | c.3694G>T p.D1232Y | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ADCY2 | c.3182G>A p.G1061E | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY8 | c.1110G>T p.Q370H | Missense Mutation (SNP) | VAF 78/425 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ADGB | c.379A>G p.N127D | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ADGRB3 | c.3455G>T p.R1152I | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ADGRG7 | c.1070A>T p.Q357L | Missense Mutation (SNP) | VAF 116/408 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ADGRL2 | c.2183G>T p.S728I (on ENST00000370717 / NM_001366005.1; = p.S715I on NM_012302.4) | Missense Mutation (SNP) | VAF 162/379 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ADGRL2 | c.4231C>G p.P1411A (on ENST00000370717 / NM_001366005.1; = p.P1355A on NM_012302.4) | Missense Mutation (SNP) | VAF 127/269 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADGRL3 | c.1395_1399del p.S466Afs*17 (on ENST00000506720 / NM_001322402.2; = p.S398Afs*17 on NM_015236.6) | Frame Shift Del (DEL) | VAF 38/186 reads (20%) | called by mutect2, varscan2
- ADGRL3 | c.2461C>A p.P821T (on ENST00000506720 / NM_001322402.2; = p.P753T on NM_015236.6) | Missense Mutation (SNP) | VAF 130/485 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRL3 | c.4635C>A p.Y1545* (on ENST00000506720 / NM_001322402.2; = p.Y1434* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 147/322 reads (46%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4636C>A p.Q1546K (on ENST00000506720 / NM_001322402.2; = p.Q1435K on NM_015236.6) | Missense Mutation (SNP) | VAF 149/326 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- ADRM1 | c.325A>T p.M109L | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- AGAP2 | c.3373C>A p.R1125S (on ENST00000547588 / NM_001122772.2; = p.R769S on NM_014770.4) | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- AGO1 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.033); called by muse, mutect2
- AHNAK2 | c.6376C>A p.P2126T | Missense Mutation (SNP) | VAF 78/331 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- AK9 | c.4238G>A p.R1413K | Missense Mutation (SNP) | VAF 175/375 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKT2 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 96/238 reads (40%) | called by muse, mutect2, varscan2
- AKT2 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 141/349 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG10 | c.649G>T p.E217* | Nonsense Mutation (SNP) | VAF 51/774 reads (7%) | called by muse, mutect2
- ANK1 | c.3787G>T p.D1263Y | Missense Mutation (SNP) | VAF 70/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ANKRD22 | c.29G>T p.C10F | Missense Mutation (SNP) | VAF 112/208 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD34C | c.1160G>A p.G387E | Missense Mutation (SNP) | VAF 42/368 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- ANKRD60 | c.116G>C p.S39T | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- APBA2 | c.1849C>A p.Q617K | Missense Mutation (SNP) | VAF 62/358 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- APBB1IP | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 131/327 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APC | c.6824A>T p.K2275M | Missense Mutation (SNP) | VAF 50/627 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- APOB | c.496G>T p.V166F | Missense Mutation (SNP) | VAF 148/351 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- ARHGEF25 | c.1531G>T p.A511S | Missense Mutation (SNP) | VAF 193/558 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ARNT2 | c.923A>C p.K308T | Missense Mutation (SNP) | VAF 47/360 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARSK | c.1342G>T p.E448* | Nonsense Mutation (SNP) | VAF 73/173 reads (42%) | called by muse, mutect2, varscan2
- ASPRV1 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ATP6V0A2 | c.2084G>A p.S695N | Missense Mutation (SNP) | VAF 55/359 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP6V0D2 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 40/917 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2
- B4GALNT3 | c.2609A>T p.D870V | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BABAM2 | c.871G>T p.A291S | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BARHL2 | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- BCHE | c.519C>A p.N173K | Missense Mutation (SNP) | VAF 215/655 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BDH1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 73/887 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BHLHE41 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.406); called by muse, varscan2
- BNC2 | c.1301C>A p.S434* | Nonsense Mutation (SNP) | VAF 148/374 reads (40%) | called by muse, mutect2, varscan2
- BTD | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 40/431 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C15orf39 | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 110/297 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C16orf78 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- C1QTNF7 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 189/404 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf94 | c.674G>T p.R225M (on ENST00000488417 / NM_001134734.2; = p.R35M on NM_032884.5) | Missense Mutation (SNP) | VAF 57/355 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- C4BPA | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 125/444 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- C7 | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 130/337 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1D | c.3979G>T p.V1327L (on ENST00000350061 / NM_001128840.3; = p.V1347L on NM_000720.4) | Missense Mutation (SNP) | VAF 238/419 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CACNA1E | c.6324G>T p.Q2108H (on ENST00000367573 / NM_001205293.3; = p.Q2065H on NM_000721.4) | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- CADM2 | c.649G>T p.A217S (on ENST00000407528 / NM_001167674.2; = p.A219S on NM_153184.4) | Missense Mutation (SNP) | VAF 161/295 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- CAMK2B | c.863T>A p.V288E | Missense Mutation (SNP) | VAF 88/329 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAPRIN2 | c.842A>T p.Y281F | Missense Mutation (SNP) | VAF 189/558 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CARMIL2 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CCDC178 | c.1039C>T p.L347F | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC27 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 130/308 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.242); called by muse, mutect2
- CCL8 | c.201G>T p.K67N | Missense Mutation (SNP) | VAF 82/400 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCT8L2 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CD300LG | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CD93 | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 90/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CDC42BPA | c.777T>A p.Y259* | Nonsense Mutation (SNP) | VAF 136/699 reads (19%) | called by muse, mutect2, varscan2
- CDC45 | c.1327G>T p.G443W | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC6 | c.583G>C p.A195P | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH19 | c.1145A>G p.E382G | Missense Mutation (SNP) | VAF 92/418 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2
- CDH23 | c.690G>C p.Q230H | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CELF3 | c.9G>T p.E3D | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); called by muse, mutect2
- CFAP69 | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 140/405 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CHD6 | c.6458G>T p.G2153V | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CHST3 | c.994G>T p.G332C | Missense Mutation (SNP) | VAF 122/260 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CHSY3 | c.2544G>T p.K848N | Missense Mutation (SNP) | VAF 65/386 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CHUK | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 187/392 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- CIR1 | c.1011G>C p.R337S | Missense Mutation (SNP) | VAF 54/535 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- CLEC1A | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 106/302 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CLTC | c.3208G>T p.A1070S | Missense Mutation (SNP) | VAF 50/474 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CNGB3 | c.1391C>A p.A464D | Missense Mutation (SNP) | VAF 118/802 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL14A1 | c.3035C>G p.P1012R | Missense Mutation (SNP) | VAF 154/845 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL14A1 | c.5376G>C p.W1792C | Missense Mutation (SNP) | VAF 287/569 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- COL20A1 | c.3606C>A p.S1202R | Missense Mutation (SNP) | VAF 83/297 reads (28%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- COL21A1 | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 169/335 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- COL24A1 | c.4541G>A p.S1514N | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- COL24A1 | c.1707G>T p.K569N | Missense Mutation (SNP) | VAF 166/363 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COL2A1 | c.3445G>T p.G1149* | Nonsense Mutation (SNP) | VAF 147/538 reads (27%) | called by muse, mutect2, varscan2
- COL4A2 | c.985G>T p.G329W | Missense Mutation (SNP) | VAF 158/319 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A2 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 146/290 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by mutect2, varscan2
- COL4A2 | c.2686G>T p.G896W | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL6A5 | c.1736G>A p.G579E | Missense Mutation (SNP) | VAF 260/645 reads (40%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- COL6A5 | c.3773C>A p.A1258D | Missense Mutation (SNP) | VAF 86/326 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by mutect2, varscan2
- COL6A5 | c.5426G>C p.G1809A (on ENST00000312481; = p.G1805A on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/575 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- COL7A1 | c.8175_8192del p.P2727_P2732del | In Frame Del (DEL) | VAF 93/223 reads (42%) | called by mutect2, varscan2
- COL8A2 | c.951G>T p.M317I | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CORO2A | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 187/350 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- COX10 | c.894G>T p.M298I | Missense Mutation (SNP) | VAF 124/638 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CPD | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 50/420 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CPLANE1 | c.8462C>T p.T2821I | Missense Mutation (SNP) | VAF 40/296 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CR2 | c.2333A>T p.Q778L | Missense Mutation (SNP) | VAF 177/603 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CROT | c.175C>G p.Q59E | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRPPA | c.938T>A p.V313E (on ENST00000407010 / NM_001368197.1; = p.V263E on NM_001101417.4) | Missense Mutation (SNP) | VAF 110/439 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CRYBG1 | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 145/326 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.6125A>G p.E2042G | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- CSMD3 | c.6890C>A p.P2297H (on ENST00000297405 / NM_001363185.1; = p.P2193H on NM_052900.3) | Missense Mutation (SNP) | VAF 153/679 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.4427C>A p.P1476Q (on ENST00000297405 / NM_001363185.1; = p.P1372Q on NM_052900.3) | Missense Mutation (SNP) | VAF 182/873 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CSMD3 | c.4361G>C p.S1454T (on ENST00000297405 / NM_001363185.1; = p.S1350T on NM_052900.3) | Missense Mutation (SNP) | VAF 75/277 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CSMD3 | c.3868C>A p.Q1290K (on ENST00000297405 / NM_001363185.1; = p.Q1186K on NM_052900.3) | Missense Mutation (SNP) | VAF 108/448 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CSMD3 | c.2091dup p.G698Wfs*11 (on ENST00000297405 / NM_001363185.1; = p.G594Wfs*11 on NM_052900.3) | Frame Shift Ins (INS) | VAF 248/692 reads (36%) | called by mutect2, varscan2
- CSNKA2IP | c.1834T>C p.S612P | Missense Mutation (SNP) | VAF 219/392 reads (56%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, varscan2
- CTNNA2 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 103/337 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTSZ | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 98/288 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CUX1 | c.2327C>G p.S776C | Missense Mutation (SNP) | VAF 82/431 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- CYFIP2 | c.1286G>C p.G429A | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- CYLC2 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 174/330 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.929); called by mutect2, varscan2
- D2HGDH | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DBX2 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 241/704 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DCC | c.613_614insT p.G205Vfs*21 | Frame Shift Ins (INS) | VAF 109/390 reads (28%) | called by mutect2, varscan2
- DDX1 | c.1283G>C p.W428S | Missense Mutation (SNP) | VAF 130/389 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND5A | c.2038A>T p.T680S | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, varscan2
- DGCR2 | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DGKI | c.1954dup p.L652Pfs*34 | Frame Shift Ins (INS) | VAF 50/250 reads (20%) | called by mutect2, varscan2
- DHCR7 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 145/220 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHRS7C | c.241T>G p.L81V | Missense Mutation (SNP) | VAF 125/287 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DHX30 | c.2797G>A p.G933S (on ENST00000445061 / NM_138615.3; = p.G894S on NM_014966.3) | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT tolerated (0.59); PolyPhen benign (0.035); called by muse, mutect2
- DHX34 | c.3295C>G p.P1099A | Missense Mutation (SNP) | VAF 21/343 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- DLX6 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- DNAH5 | c.8416A>T p.N2806Y | Missense Mutation (SNP) | VAF 159/375 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- DNAH7 | c.5198C>T p.P1733L | Missense Mutation (SNP) | VAF 166/399 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DPPA4 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 119/422 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DPY19L3 | c.1883G>A p.R628K | Missense Mutation (SNP) | VAF 90/412 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DSC3 | c.731C>A p.T244K | Missense Mutation (SNP) | VAF 114/397 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- DSG1 | c.2010A>C p.Q670H | Missense Mutation (SNP) | VAF 47/403 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- DUOX2 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DUSP10 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 122/587 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EDEM3 | c.2167A>G p.I723V | Missense Mutation (SNP) | VAF 52/509 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EEPD1 | c.16G>T p.G6C | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EFCC1 | c.1696C>G p.L566V | Missense Mutation (SNP) | VAF 89/488 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ELMO1 | c.1190G>T p.R397L | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- EMC8 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ENTPD2 | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 201/371 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- EPB41L3 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 138/412 reads (33%) | called by muse, mutect2, varscan2
- EPHA5 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 60/427 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- EPHA7 | c.1938A>T p.E646D | Missense Mutation (SNP) | VAF 224/430 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ESR1 | c.1115T>A p.L372H | Missense Mutation (SNP) | VAF 124/290 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EVC | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 122/328 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EVC2 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANK1 | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 366/600 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAP | c.989G>T p.W330L | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FASTKD5 | c.1659G>T p.M553I | Missense Mutation (SNP) | VAF 123/391 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FAT2 | c.10438G>C p.D3480H | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- FBN2 | c.5012G>T p.G1671V | Missense Mutation (SNP) | VAF 178/413 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- FBXO5 | c.321A>T p.Q107H | Missense Mutation (SNP) | VAF 63/381 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FCRL3 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 150/530 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FGD4 | c.1363G>T p.V455L | Missense Mutation (SNP) | VAF 30/557 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- FGG | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 161/364 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FMN1 | c.2442G>C p.K814N (on ENST00000616417 / NM_001277313.2; = p.K591N on NM_001103184.4) | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FOXD3 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FOXN4 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXP2 | c.1493A>T p.Y498F | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- FSCN3 | c.1138G>T p.G380W | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- FSIP2 | c.1073C>A p.T358K | Missense Mutation (SNP) | VAF 35/198 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FSIP2 | c.9517G>T p.E3173* | Nonsense Mutation (SNP) | VAF 148/337 reads (44%) | called by muse, mutect2, varscan2
- FXR1 | c.1605C>T p.V535= | Splice Region (SNP) | VAF 104/330 reads (32%) | called by muse, mutect2, varscan2
- GABRA2 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 141/602 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GABRG1 | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 218/543 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GATA5 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- GATB | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF2 | c.737C>A p.P246Q | Missense Mutation (SNP) | VAF 159/314 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GEMIN5 | c.3086G>C p.W1029S | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GGT1 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GJE1 | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 122/311 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLB1L3 | c.1408C>A p.H470N | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLIPR1L2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- GLRA3 | c.712+1G>T p.X238_splice | Splice Site (SNP) | VAF 146/267 reads (55%) | called by muse, mutect2, varscan2
- GNAQ | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1904C>A p.A635E | Missense Mutation (SNP) | VAF 157/539 reads (29%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- GPATCH2 | c.1400A>C p.E467A | Missense Mutation (SNP) | VAF 71/436 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- GPC6 | c.558C>A p.Y186* | Nonsense Mutation (SNP) | VAF 47/316 reads (15%) | called by muse, varscan2
- GPD2 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 129/543 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRAMD1C | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 108/336 reads (32%) | called by muse, mutect2, varscan2
- GRIN3A | c.1409A>T p.H470L | Missense Mutation (SNP) | VAF 202/380 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- GTF2IRD1 | c.1566G>T p.M522I | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GZMB | c.712C>G p.H238D | Missense Mutation (SNP) | VAF 33/357 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- H2BW1 | c.201T>G p.H67Q | Missense Mutation (SNP) | VAF 125/266 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- H3-5 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 36/600 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2
- HAGH | c.383A>C p.D128A | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- HDAC11 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 66/315 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- HECW2 | c.3536A>T p.Q1179L | Missense Mutation (SNP) | VAF 68/280 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- HERC2 | c.1732G>T p.G578W | Missense Mutation (SNP) | VAF 40/342 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HHLA1 | c.868C>T p.L290F | Missense Mutation (SNP) | VAF 150/696 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HMX3 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 229/395 reads (58%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- HOXA4 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 72/246 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HOXA4 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- HRG | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- IBTK | c.1156G>T p.G386W | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IFRD1 | c.1097A>T p.D366V | Missense Mutation (SNP) | VAF 133/359 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGF2R | c.6716C>T p.S2239F | Missense Mutation (SNP) | VAF 161/345 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGFN1 | c.2153G>T p.R718L (on ENST00000295591 / NM_001367841.1; = p.R3175L on NM_001164586.2) | Missense Mutation (SNP) | VAF 86/354 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- IGKV3-7 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 25/280 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); called by muse, mutect2
- IGLV2-14 | c.50C>A p.S17Y | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- IGLV7-46 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGSF21 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 89/199 reads (45%) | called by muse, mutect2, varscan2
- IL19 | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 82/502 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- IL1RAP | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 135/378 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- IL7R | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 110/319 reads (34%) | called by muse, mutect2, varscan2
- INPP5J | c.524del p.G175Dfs*11 | Frame Shift Del (DEL) | VAF 124/297 reads (42%) | called by mutect2, varscan2
- INSM2 | c.706G>C p.V236L | Missense Mutation (SNP) | VAF 94/348 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- IPO8 | c.2929C>T p.Q977* | Nonsense Mutation (SNP) | VAF 148/393 reads (38%) | called by muse, mutect2, varscan2
- IRAK4 | c.890A>T p.N297I | Missense Mutation (SNP) | VAF 98/608 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ITIH1 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 232/367 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITIH6 | c.2779C>G p.L927V | Missense Mutation (SNP) | VAF 162/379 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ITPR3 | c.6781A>G p.I2261V | Missense Mutation (SNP) | VAF 107/527 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- JPH2 | c.1787C>A p.P596H | Missense Mutation (SNP) | VAF 74/267 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KAT6A | c.5191A>G p.I1731V | Missense Mutation (SNP) | VAF 104/374 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- KATNIP | c.4757A>G p.Q1586R | Missense Mutation (SNP) | VAF 117/279 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- KCNA10 | c.1240T>A p.W414R | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCND2 | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 117/479 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- KEAP1 | c.544del p.S182Afs*48 | Frame Shift Del (DEL) | VAF 130/240 reads (54%) | called by mutect2, varscan2
- KIF1A | c.2848G>C p.G950R | Missense Mutation (SNP) | VAF 38/526 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2
- KIF20A | c.2089C>G p.Q697E | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF25 | c.756del p.N253Tfs*29 (on ENST00000354419 / NM_030615.2; = p.N253Tfs*32 on NM_005355.3) | Frame Shift Del (DEL) | VAF 172/344 reads (50%) | called by mutect2, varscan2
- KIF2B | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 48/318 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- KIF7 | c.3448G>C p.D1150H | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIR2DL3 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 35/313 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KIR3DL1 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- KLHL1 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 161/372 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- KMO | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.097); called by mutect2, varscan2
- KMT2A | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 235/379 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KMT2C | c.4046G>A p.R1349Q | Missense Mutation (SNP) | VAF 36/419 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- KRBA1 | c.1311A>T p.R437S | Missense Mutation (SNP) | VAF 61/264 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- KRT6A | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 138/550 reads (25%) | called by muse, varscan2
- LACTB | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- LAD1 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 28/134 reads (21%) | called by muse, mutect2, varscan2
- LCTL | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by mutect2, varscan2
- LHCGR | c.1995T>A p.N665K | Missense Mutation (SNP) | VAF 84/513 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- LMTK2 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 46/361 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- LNPEP | c.428A>G p.K143R | Missense Mutation (SNP) | VAF 103/391 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by mutect2, varscan2
- LRATD1 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 124/298 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- LRGUK | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRP4 | c.1683G>T p.L561F | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC4B | c.239T>A p.V80D | Missense Mutation (SNP) | VAF 59/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LRRC55 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 72/533 reads (14%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- LRRC7 | c.4411C>G p.Q1471E (on ENST00000651989 / NM_001370785.2; = p.Q1391E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/367 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LRRC9 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 137/488 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRTM1 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 121/306 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LTBP2 | c.3651G>A p.Q1217= | Splice Region (SNP) | VAF 64/192 reads (33%) | called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.208C>A p.H70N | Missense Mutation (SNP) | VAF 36/517 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- LZTS1 | c.1334T>A p.L445Q | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- MAGEL2 | c.1420C>A p.Q474K | Missense Mutation (SNP) | VAF 140/397 reads (35%) | SIFT tolerated, low confidence (0.9); called by muse, mutect2, varscan2
- MAMDC2 | c.774C>A p.D258E | Missense Mutation (SNP) | VAF 268/514 reads (52%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MAP3K20 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 70/364 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAPKBP1 | c.3656C>T p.A1219V (on ENST00000456763 / NM_001128608.2; = p.A1213V on NM_014994.3) | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MARCOL | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT tolerated (0.73); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MBD2 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 62/159 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MC3R | c.805C>A p.P269T | Missense Mutation (SNP) | VAF 52/610 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MDGA1 | c.1630_1635del p.S544_S545del | In Frame Del (DEL) | VAF 128/258 reads (50%) | called by mutect2, varscan2
- MDN1 | c.9302G>T p.W3101L | Missense Mutation (SNP) | VAF 46/371 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MEF2C | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 144/365 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.103); called by mutect2, varscan2
- MEGF6 | c.445T>C p.C149R | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAM | c.2948G>C p.C983S | Missense Mutation (SNP) | VAF 71/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIA3 | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 105/446 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- MLLT3 | c.376A>C p.N126H | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MN1 | c.1877C>A p.A626E | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MOB3B | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 136/387 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOCOS | c.883G>T p.A295S | Missense Mutation (SNP) | VAF 85/273 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MRC1 | c.2779A>T p.S927C | Missense Mutation (SNP) | VAF 196/393 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- MRGPRG | c.656G>T p.S219I | Missense Mutation (SNP) | VAF 142/286 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MROH5 | c.2530C>A p.L844M | Missense Mutation (SNP) | VAF 155/549 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MRPS7 | c.128A>T p.D43V | Missense Mutation (SNP) | VAF 38/422 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2
- MRPS9 | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- MS4A13 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A18 | c.640G>T p.V214L (on ENST00000398983; = p.V216L on NM_001354471.1) | Missense Mutation (SNP) | VAF 62/302 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.052); called by mutect2, varscan2
- MUC5B | c.11030C>A p.T3677N | Missense Mutation (SNP) | VAF 189/345 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- MYO18B | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 138/332 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYRF | c.791G>T p.S264I (on ENST00000278836 / NM_001127392.3; = p.S255I on NM_013279.4) | Missense Mutation (SNP) | VAF 124/436 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- MYRFL | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 218/632 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NACAD | c.3686C>A p.P1229H | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- NAPA | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 75/355 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NAV3 | c.6150C>A p.H2050Q (on ENST00000397909 / NM_001024383.2; = p.H2028Q on NM_014903.6) | Missense Mutation (SNP) | VAF 246/720 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- NCAPD3 | c.2237+1G>T p.X746_splice | Splice Site (SNP) | VAF 177/321 reads (55%) | called by muse, mutect2, varscan2
- NEXMIF | c.2238G>A p.M746I | Missense Mutation (SNP) | VAF 56/416 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NKX3-2 | c.385G>T p.V129F | Missense Mutation (SNP) | VAF 181/404 reads (45%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NLRC5 | c.377G>C p.S126T | Missense Mutation (SNP) | VAF 158/324 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- NLRC5 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 172/365 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NLRP14 | c.379A>T p.R127* | Nonsense Mutation (SNP) | VAF 116/206 reads (56%) | called by muse, mutect2, varscan2
- NLRP3 | c.1937A>T p.D646V | Missense Mutation (SNP) | VAF 75/411 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NLRP8 | c.1142G>A p.S381N | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NOD1 | c.2426A>G p.K809R | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NOP14 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 54/630 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOP53 | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 69/363 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NOTCH4 | c.2684T>G p.I895R | Missense Mutation (SNP) | VAF 114/251 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NR0B1 | c.1388T>C p.L463P | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NSMAF | c.1312G>T p.G438C | Missense Mutation (SNP) | VAF 81/411 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NTNG2 | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 99/170 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUTM1 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- OASL | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 48/279 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPN1LW | c.37C>A p.R13S | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- OPN1MW | c.767C>A p.S256Y | Missense Mutation (SNP) | VAF 98/238 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10W1 | c.665C>A p.A222D | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- OR12D3 | c.92T>C p.I31T | Missense Mutation (SNP) | VAF 68/678 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- OR13G1 | c.706T>A p.S236T | Missense Mutation (SNP) | VAF 72/431 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR14A2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 108/278 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- OR14C36 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR1A2 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OR2B6 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 54/426 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR2J2 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 171/374 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- OR4C15 | c.235G>C p.V79L (on ENST00000314644; = p.V25L on NM_001001920.2) | Missense Mutation (SNP) | VAF 53/566 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); called by muse, mutect2
- OR51E1 | c.346A>G p.T116A | Missense Mutation (SNP) | VAF 230/413 reads (56%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- OR5AS1 | c.291dup p.A98Cfs*12 | Frame Shift Ins (INS) | VAF 183/435 reads (42%) | called by mutect2, varscan2
- OR5D13 | c.143T>A p.I48K | Missense Mutation (SNP) | VAF 46/465 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- OR5J2 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 54/456 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); called by muse, varscan2
- OR5K4 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 86/355 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OR5M1 | c.704A>T p.H235L | Missense Mutation (SNP) | VAF 169/412 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR5T1 | c.974A>T p.K325M | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- OR8H3 | c.142T>G p.L48V | Missense Mutation (SNP) | VAF 56/620 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.226); called by muse, mutect2
- OR8S1 | c.333A>T p.E111D | Missense Mutation (SNP) | VAF 249/606 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL5 | c.937G>T p.D313Y | Missense Mutation (SNP) | VAF 165/297 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- OTOGL | c.5395C>A p.P1799T (on ENST00000547103; = p.P1790T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 138/462 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PABPC5 | c.582T>A p.D194E | Missense Mutation (SNP) | VAF 74/488 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PBRM1 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 229/381 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PCDH1 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 61/417 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PCDHA12 | c.2325C>A p.S775R | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PCDHA2 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); called by muse, mutect2
- PCDHA8 | c.1385T>C p.V462A | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- PCDHB16 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PCDHB7 | c.23C>A p.A8D | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHGA8 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNX1 | c.5683G>T p.G1895W | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCNX1 | c.6900G>A p.W2300* | Nonsense Mutation (SNP) | VAF 58/333 reads (17%) | called by muse, mutect2, varscan2
- PCNX3 | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 59/389 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PCOLCE2 | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 46/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PDE6B | c.587T>A p.L196H | Missense Mutation (SNP) | VAF 178/435 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PDHA2 | c.576T>A p.Y192* | Nonsense Mutation (SNP) | VAF 114/440 reads (26%) | called by muse, mutect2, varscan2
- PDLIM7 | c.390G>T p.Q130H | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEG3 | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 147/386 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PHKA2 | c.173del p.G58Afs*25 | Frame Shift Del (DEL) | VAF 170/358 reads (47%) | called by mutect2, varscan2
- PHLPP1 | c.460G>C p.A154P | Missense Mutation (SNP) | VAF 117/522 reads (22%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- PIK3C2G | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 266/643 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PKDREJ | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PKHD1L1 | c.7966T>A p.C2656S | Missense Mutation (SNP) | VAF 130/619 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- PKHD1L1 | c.8828G>T p.R2943M | Missense Mutation (SNP) | VAF 255/546 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PLAGL2 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 43/553 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLB1 | c.346T>A p.Y116N | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLXNA3 | c.5145G>T p.W1715C | Missense Mutation (SNP) | VAF 87/169 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA4 | c.2341T>A p.L781M | Missense Mutation (SNP) | VAF 75/426 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- PLXNB2 | c.3532G>T p.G1178C | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNB3 | c.3551A>T p.E1184V | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- PM20D1 | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 113/437 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- PNMA3 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 158/332 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- POLR2B | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 75/537 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- POU2F1 | c.333G>A p.G111= (on ENST00000541643 / NM_001365848.1; = p.G134= on NM_002697.4) | Splice Region (SNP) | VAF 113/309 reads (37%) | called by muse, mutect2, varscan2
- POU3F3 | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PPFIBP1 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 62/864 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- PPM1N | c.448C>A p.R150S | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPP1R16A | c.1030A>G p.S344G | Missense Mutation (SNP) | VAF 41/297 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- PPP2R3A | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 141/529 reads (27%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP6R2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, varscan2
- PRDM2 | c.3338G>T p.R1113M | Missense Mutation (SNP) | VAF 49/387 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- PRDM2 | c.3339G>T p.R1113S | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PREPL | c.1426G>T p.V476L | Missense Mutation (SNP) | VAF 52/423 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PROB1 | c.1582G>T p.G528C | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PROM2 | c.684T>C p.G228= | Splice Region (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- PRR16 | c.468T>A p.N156K (on ENST00000407149 / NM_001300783.2; = p.N133K on NM_016644.2) | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- PSMB9 | c.584dup p.V196Gfs*17 | Frame Shift Ins (INS) | VAF 207/412 reads (50%) | called by mutect2, varscan2
- PTPRH | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 217/418 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PTPRQ | c.191C>A p.S64Y (on ENST00000616559; = p.S22Y on NM_001145026.2) | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- PTPRR | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 192/554 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PXDN | c.4206+1G>A p.X1402_splice | Splice Site (SNP) | VAF 24/149 reads (16%) | called by muse, mutect2, varscan2
- PXDN | c.1051A>G p.T351A | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- PXDNL | c.4304C>A p.P1435H | Missense Mutation (SNP) | VAF 37/424 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PXDNL | c.461A>T p.H154L | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- R3HDML | c.674G>T p.C225F | Missense Mutation (SNP) | VAF 110/363 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- RAB3C | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RAB4B | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 107/215 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- RALGAPA2 | c.3886G>T p.D1296Y | Missense Mutation (SNP) | VAF 156/342 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- RAPH1 | c.1781G>C p.R594T | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- RBBP6 | c.2912C>G p.T971R | Missense Mutation (SNP) | VAF 84/352 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- RBM46 | c.26C>A p.T9K | Missense Mutation (SNP) | VAF 152/270 reads (56%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- RERE | c.1433dup p.S479Vfs*3 | Frame Shift Ins (INS) | VAF 82/200 reads (41%) | called by mutect2, varscan2
- RFX4 | c.559C>A p.L187I (on ENST00000392842 / NM_213594.3; = p.L93I on NM_032491.6) | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2
- RIMS2 | c.4385G>T p.G1462V (on ENST00000666250 / NM_001348490.2; = p.G1033V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/583 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF113A | c.1032G>T p.*344Yext*6 | Nonstop Mutation (SNP) | VAF 33/192 reads (17%) | called by muse, mutect2, varscan2
- RNF169 | c.577-18_598del p.X193_splice | Splice Site (DEL) | VAF 102/280 reads (36%) | called by mutect2, varscan2
- RNF2 | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RP1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.035); called by muse, mutect2
- RP1L1 | c.7166G>T p.R2389M | Missense Mutation (SNP) | VAF 41/300 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- RRP9 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 129/234 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- RTL6 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 130/316 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0); called by mutect2, varscan2
- RTN4RL1 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 148/232 reads (64%) | SIFT tolerated (0.3); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- RYR1 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 158/329 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR1 | c.14810T>A p.I4937N | Missense Mutation (SNP) | VAF 23/305 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RYR2 | c.7211C>T p.P2404L | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- S1PR4 | c.232C>G p.R78G | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SATL1 | c.439C>G p.Q147E (on ENST00000395409; = p.Q334E on NM_001012980.2) | Missense Mutation (SNP) | VAF 184/390 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SEC23B | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 99/415 reads (24%) | called by muse, mutect2, varscan2
- SEC24D | c.973A>G p.M325V | Missense Mutation (SNP) | VAF 183/370 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- SEMA6A | c.2887C>A p.P963T | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERINC3 | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 137/399 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SERPINE2 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 118/396 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SEZ6L | c.2819C>A p.A940D | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.404); called by mutect2, varscan2
- SH3D21 | c.2149_2151dup p.D717dup (on ENST00000453908 / NM_001162530.2; = p.D606dup on NM_024676.5) | In Frame Ins (INS) | VAF 36/271 reads (13%) | called by mutect2, varscan2
- SIGLEC6 | c.915G>T p.E305D | Missense Mutation (SNP) | VAF 168/399 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SLC16A5 | c.1024A>G p.M342V | Missense Mutation (SNP) | VAF 50/280 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SLC17A9 | c.212G>T p.W71L | Missense Mutation (SNP) | VAF 108/366 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- SLC1A7 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 102/290 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SLC27A6 | c.971G>T p.R324I | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SLC43A1 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 51/381 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SLC45A2 | c.572G>C p.G191A | Missense Mutation (SNP) | VAF 78/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC6A2 | c.1199G>C p.G400A | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.734); called by muse, varscan2
- SLITRK4 | c.931_932insG p.K311Rfs*61 | Frame Shift Ins (INS) | VAF 180/388 reads (46%) | called by mutect2, varscan2
- SMARCC2 | c.2785G>C p.A929P | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- SMG8 | c.514G>T p.G172W | Missense Mutation (SNP) | VAF 140/304 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by mutect2, varscan2
- SMIM1 | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SOBP | c.1408G>T p.G470W | Missense Mutation (SNP) | VAF 21/241 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORD | c.634A>T p.K212* | Nonsense Mutation (SNP) | VAF 54/261 reads (21%) | called by muse, mutect2, varscan2
- SOX6 | c.1956C>A p.S652R (on ENST00000528429 / NM_001145819.2; = p.S625R on NM_017508.3) | Missense Mutation (SNP) | VAF 107/193 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA19 | c.484C>G p.P162A | Missense Mutation (SNP) | VAF 192/374 reads (51%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA3 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT tolerated, low confidence (0.5); called by muse, mutect2
- SPDL1 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 90/245 reads (37%) | called by muse, mutect2, varscan2
- SREBF2 | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SSTR5 | c.366C>A p.N122K | Missense Mutation (SNP) | VAF 45/360 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STOX1 | c.1894G>A p.G632R | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SULT4A1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- SULT4A1 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SYT16 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SYTL2 | c.2000+1G>T p.X667_splice (on ENST00000528231 / NM_001162951.2; = p.X643_splice on NM_032943.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 180/277 reads (65%) | called by muse, mutect2, varscan2
- TAF4B | c.489G>T p.P163= | Splice Region (SNP) | VAF 91/243 reads (37%) | called by muse, mutect2, varscan2
- TAP1 | c.1031T>A p.I344N | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TARM1 | c.386G>C p.G129A (on ENST00000616041 / NM_001330650.1; = p.G121A on NM_001135686.3) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TAS2R41 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D3B | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 150/763 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- TBC1D9 | c.2930G>T p.G977V | Missense Mutation (SNP) | VAF 118/535 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBX5 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 43/475 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2
- TDRKH | c.423G>T p.G141= | Splice Region (SNP) | VAF 108/313 reads (35%) | called by muse, mutect2, varscan2
- TEKT5 | c.980_987del p.L327Sfs*19 | Frame Shift Del (DEL) | VAF 54/273 reads (20%) | called by mutect2, varscan2
- TENM1 | c.1610A>T p.N537I | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TENM2 | c.6709C>A p.P2237T (on ENST00000518659 / NM_001122679.2; = p.P1998T on NM_001080428.3) | Missense Mutation (SNP) | VAF 155/379 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TENM3 | c.6868G>C p.D2290H | Missense Mutation (SNP) | VAF 249/450 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- TEPP | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 21/157 reads (13%) | called by muse, mutect2, varscan2
- TEX51 | c.197T>A p.L66H | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TFF2 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TG | c.845G>A p.R282K | Missense Mutation (SNP) | VAF 159/732 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TGIF2LX | c.497A>G p.Q166R | Missense Mutation (SNP) | VAF 154/313 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TGM7 | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- THSD7B | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TIMD4 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- TMEM161B | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TMEM179 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 96/330 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- TMEM229A | c.460_471del p.P154_L157del | In Frame Del (DEL) | VAF 82/274 reads (30%) | called by mutect2, varscan2
- TMTC2 | c.2503A>G p.K835E | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNNI3K | c.1668-1G>C p.X556_splice | Splice Site (SNP) | VAF 37/299 reads (12%) | called by muse, mutect2, varscan2
- TNR | c.1553C>A p.T518N | Missense Mutation (SNP) | VAF 131/343 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TOP2B | c.456G>C p.K152N (on ENST00000264331 / NM_001330700.2; = p.K147N on NM_001068.3) | Missense Mutation (SNP) | VAF 165/277 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TOPAZ1 | c.73C>G p.R25G | Missense Mutation (SNP) | VAF 193/306 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- TPR | c.6623G>T p.G2208V | Missense Mutation (SNP) | VAF 151/371 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAJ46 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 114/401 reads (28%) | PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRAP1 | c.1951A>T p.I651F | Missense Mutation (SNP) | VAF 141/318 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TRAPPC8 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, varscan2
- TRAV40 | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRBV23-1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 117/304 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TRBV27 | c.31del p.L11Ffs*4 | Frame Shift Del (DEL) | VAF 135/343 reads (39%) | called by mutect2, varscan2
- TRDD3 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 81/272 reads (30%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRHDE | c.1414del p.V472Lfs*18 | Frame Shift Del (DEL) | VAF 127/424 reads (30%) | called by mutect2, varscan2
- TRIM64B | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 98/355 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM66 | c.2785G>A p.V929I | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRIM9 | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 105/336 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TRIP10 | c.1317C>A p.D439E (on ENST00000313244 / NM_001288962.2; = p.D383E on NM_004240.4) | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TTC28 | c.2716G>C p.V906L | Missense Mutation (SNP) | VAF 179/401 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TTLL4 | c.1237G>T p.V413F | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- TTN | c.98916T>A p.D32972E (on ENST00000591111; = p.D25548E on NM_003319.4) | Missense Mutation (SNP) | VAF 38/402 reads (9%) | PolyPhen probably damaging (0.996); called by muse, mutect2
- TTN | c.77872G>T p.G25958C (on ENST00000591111; = p.G18534C on NM_003319.4) | Missense Mutation (SNP) | VAF 37/341 reads (11%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.75548C>A p.T25183N (on ENST00000591111; = p.T17759N on NM_003319.4) | Missense Mutation (SNP) | VAF 96/460 reads (21%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TTN | c.71793C>A p.N23931K (on ENST00000591111; = p.N16507K on NM_003319.4) | Missense Mutation (SNP) | VAF 146/578 reads (25%) | PolyPhen benign (0.372); called by muse, mutect2, varscan2
- TTN | c.64003C>T p.L21335F (on ENST00000591111; = p.L13911F on NM_003319.4) | Missense Mutation (SNP) | VAF 54/565 reads (10%) | PolyPhen possibly damaging (0.592); called by muse, mutect2
- TTN | c.58436A>G p.N19479S (on ENST00000591111; = p.N12055S on NM_003319.4) | Missense Mutation (SNP) | VAF 139/536 reads (26%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTN | c.20352G>C p.L6784F (on ENST00000591111; = p.L5857F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/503 reads (26%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUBGCP6 | c.5032A>G p.K1678E | Missense Mutation (SNP) | VAF 136/296 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TXNDC5 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 232/435 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- U2SURP | c.2670G>T p.E890D | Missense Mutation (SNP) | VAF 87/272 reads (32%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- UBE3A | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- UBR5 | c.6177A>G p.P2059= | Splice Region (SNP) | VAF 240/542 reads (44%) | called by muse, mutect2, varscan2
- UNC13A | c.2737G>A p.A913T | Missense Mutation (SNP) | VAF 44/289 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- UNC79 | c.7091G>T p.G2364V (on ENST00000393151 / NM_001346218.2; = p.G2187V on NM_020818.5) | Missense Mutation (SNP) | VAF 170/644 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- UNC80 | c.2402del p.G801Dfs*18 | Frame Shift Del (DEL) | VAF 120/528 reads (23%) | called by mutect2, varscan2
- UNC80 | c.5014-1G>T p.X1672_splice | Splice Site (SNP) | VAF 73/276 reads (26%) | called by muse, mutect2, varscan2
- USH2A | c.11425G>T p.V3809F | Missense Mutation (SNP) | VAF 80/383 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- USP17L4 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP2 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 224/352 reads (64%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- UXS1 | c.1121G>T p.W374L | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VAV3 | c.717+1G>C p.X239_splice | Splice Site (SNP) | VAF 111/228 reads (49%) | called by muse, mutect2, varscan2
- VLDLR | c.1187-1G>C p.X396_splice | Splice Site (SNP) | VAF 59/159 reads (37%) | called by muse, mutect2, varscan2
- WIPF3 | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 102/366 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XIRP2 | c.380A>T p.E127V (on ENST00000628543; = p.E302V on NM_152381.6) | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- XYLT1 | c.1454A>G p.E485G | Missense Mutation (SNP) | VAF 54/380 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB46 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZC4H2 | c.396G>T p.L132F | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ZFHX3 | c.6501C>A p.N2167K | Missense Mutation (SNP) | VAF 39/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZIM2 | c.1468C>G p.Q490E | Missense Mutation (SNP) | VAF 166/362 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZNF180 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 185/739 reads (25%) | called by muse, mutect2, varscan2
- ZNF28 | c.1621C>T p.H541Y | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF300 | c.806G>T p.C269F | Missense Mutation (SNP) | VAF 45/366 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF407 | c.3187A>G p.R1063G | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- ZNF467 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 78/376 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- ZNF468 | c.859T>G p.F287V | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ZNF676 | c.884G>T p.S295I (on ENST00000650058; = p.S263I on NM_001001411.3) | Missense Mutation (SNP) | VAF 141/280 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- ZNF676 | c.253T>A p.F85I (on ENST00000650058; = p.F53I on NM_001001411.3) | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF683 | c.439del p.C147Afs*91 | Frame Shift Del (DEL) | VAF 38/244 reads (16%) | called by mutect2, varscan2
- ZNF69 | c.1126C>T p.Q376* | Nonsense Mutation (SNP) | VAF 47/273 reads (17%) | called by muse, mutect2, varscan2
- ZNF717 | c.1251C>A p.H417Q | Missense Mutation (SNP) | VAF 180/403 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF724 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 138/298 reads (46%) | called by muse, mutect2, varscan2
- ZNF804A | c.1756C>A p.H586N | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF83 | c.6T>A p.H2Q | Missense Mutation (SNP) | VAF 99/320 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNHIT3 | c.257G>C p.R86T | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- ZP3 | c.1046G>T p.R349L (on ENST00000394857 / NM_001110354.2; = p.R298L on NM_007155.6) | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- AASS | c.732G>A p.E244= | Silent (SNP) | VAF 41/332 reads (12%) | called by muse, mutect2, varscan2
- ABCA10 | c.645A>T p.T215= | Silent (SNP) | VAF 94/224 reads (42%) | called by muse, mutect2
- ABCA8 | c.105G>A p.L35= | Silent (SNP) | VAF 89/204 reads (44%) | called by muse, mutect2, varscan2
- ABCB1 | c.3240C>G p.V1080= | Silent (SNP) | VAF 76/370 reads (21%) | called by muse, mutect2, varscan2
- ADGRA2 | c.735G>A p.L245= | Silent (SNP) | VAF 231/392 reads (59%) | catalogued as rs1395850110; called by muse, mutect2, varscan2
- ADGRA3 | c.2952A>G p.S984= | Silent (SNP) | VAF 133/607 reads (22%) | called by muse, mutect2, varscan2
- ADGRV1 | c.2346C>T p.S782= | Silent (SNP) | VAF 61/340 reads (18%) | catalogued as rs763097636; called by muse, mutect2, varscan2
249 further variants in this file (0 protein-altering or splice-affecting, 210 silent, 39 other) are not listed here.
